TARGET case TARGET-30-PATVDY — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e3ec35c7-bc0f-54a5-9c96-7f4a2dcec663

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 3.4 years (1,248 days); Year of diagnosis: 2010; Days to last follow up: 3,072 days (8.4 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Percent tumor nuclei: 75.
   Treatment given: Protocol identifier: AEPI07N1.
   Treatment given: Protocol identifier: ANBL0532.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0032.

Follow-up (2 entries)
- Days to follow up: 647 days (1.8 years); Progression or recurrence anatomic site: Brain, NOS; Days to first event: 647 days (1.8 years); First event: Relapse.
- Days to follow up: 3,072 days (8.4 years); Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PATVDY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-30-PATVDY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3072
- Protocol: ANBL00B1, ANBL0532, AEPI07N1, ANBL0032
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.85
- ICDO Description: Retroperitoneum Periadrenal tissue Perinephric tissue
- Site of Relapse: Other, specify: Brain
